Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5740, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5740-01A (Primary Tumor).

Diagnosis

1. Tumor-free fatty tissue.
2. – 4. Tumor-free pelvic lymph nodes on both sides.
5. Tumor-free seminal vesicle tissue.
6. Prostate with variously extensive foci of an adenocarcinoma. Gleason score 3+4.
Largest tumor spread in the left lateral zone, here infiltration of the organ capsule.
A few further small tumor foci in the right lobe.
Tumor limited to the prostate, no infiltration of the periprostatic tissue.
Slight gnarled hyperplasia.
Tumor-free seminal vesicles.
Stage pT2c G2 N0 R0.
-
-
- TCGA-CH-5740

Source: NCI Genomic Data Commons file e60ba9d3-60aa-46df-b14b-b95f033f7ace (TCGA-CH-5740.25992D81-7441-4D60-A773-457618DCEDBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).